CCDI case PBCWLC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a8472904-3798-4391-b657-24b5b2b2a47c

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1MAJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0E1MB1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1MC5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
